Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6929, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6929-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 6

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: 1. Partial organ resection – rectum and sigmoid colon

2. Total organ resection – appendix

3. Multiple organ resection – oviducts and ovary

4. Total organ resection – left ovary

5. Scrapings – small intestine, mesentery

6. Lesion excision - intestine

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: Left oviducts and ovary

Examination performed on:

Macroscopic description:

1. A 18.4 cm length of the large intestine with a 20 x 4 x 3.5 cm piece of mesentery. Ulcerous tumour sized 3.6 x 3.8 x 0.9 cm found in the mucosa. The lesion surrounds 90% of the intestine circumference, is located 8.6 cm from one of the incision lines and 8.8 cm from the other.

2. Appendix of 5.9 cm in length.

3. Left ovary sized: 4.2 x 2.3 x 2.2 cm with oviduct of 10 cm in length.

4. Fragment of the ovary sized: 4.4 x 2.7 x 1.3 cm with a cyst of 1.5 cm.

5. Many specimens of 0.8 cm diameter.

6. Two tissue rings of 2 cm diameter.

Microscopic description:

1. Adenocarcinoma tubulare (G2). Infiltratio carcinomatosa telae adiposae pericolicae.

Intensive inflammatory infiltration around the tumour.

Incision lines free of neoplastic lesions.

Metastases carcinomatosa in lymphonodo (NO I/XII).

Histopathological Diagnosis:

1. Adenocarcinoma tubulare coli. Tubular adenocarcinoma of the colon. Metastases carcinomatosa in lymphonodo. Cancer metastases in the lymph nodes (No I/XII). (G2, Dukes C, Astler - Coller C2, pT3, pN1).

2. Appendicitis chronica. Chronic appendicitis.

3. Corpus luteum haemorrhagicum ovarii. Haemorrhagic corpus luteum of the ovary

4. Metastasis carcinomatosa in ovario: adenocarcinoma tubulare cologenes. Cancer metastases into ovary.

5. Fragment of fibrous tissue with inflammatory infiltration.

6. Neoplastic lesions not detected.

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT

Source: NCI Genomic Data Commons file e0420375-a1a8-4011-99c6-d9b8fc57117d (TCGA-D5-6929.D6EC7D7D-FC73-4411-B42D-19EF642FDB36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).